Somatic mutation profile of tumor specimen TCGA-SP-A6QG-01A (aliquot TCGA-SP-A6QG-01A-12D-A35I-08) from TCGA case TCGA-SP-A6QG, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 35.2 years (12,874 days).
Specimen TCGA-SP-A6QG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fafed9c-f6e2-47ed-819a-d4608629f01d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SP-A6QG-10A (Blood Derived Normal), aliquot TCGA-SP-A6QG-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74dc6cf6-bc14-4540-b0cf-cbbbcc39dc6c

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDHGA4 | c.2366C>T p.S789F | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as rs375569568; called by muse, mutect2
- TRMT2B | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MICU3 | c.1101C>G p.L367= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs1215448578, COSV58848389; called by muse, mutect2, varscan2
- VPS13B | c.3561C>T p.V1187= | Silent (SNP) | VAF 32/167 reads (19%) | called by muse, mutect2, varscan2
